Somatic mutation profile of tumor specimen TARGET-30-PARYVD-01A (aliquot TARGET-30-PARYVD-01A-01D) from TARGET case TARGET-30-PARYVD, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (769 days).
Specimen TARGET-30-PARYVD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ccf12a5-48dd-47f5-8490-f04a27c32d4b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARYVD-10A (Blood Derived Normal), aliquot TARGET-30-PARYVD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40a57505-fc7b-4569-9f8b-7f2ea3b905e9

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRCAP | c.*512C>A | 3'UTR (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
